Somatic mutation profile of tumor specimen 0DLSYE from CCDI case PBBZNR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 1.4 years (526 days).
Specimen 0DLSYE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ccacee0-a012-4a71-a698-93562db67644.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLSX9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3507c96f-af79-4813-8265-13aa543150a1

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRRTM2 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.228); catalogued as rs779631552; called by muse, mutect2, varscan2
- OLFM1 | c.1441C>T p.R481C (on ENST00000371793 / NM_001282611.2; = p.R463C on NM_014279.5) | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1401300491, COSV53277207; called by muse, mutect2, varscan2
- SART1 | c.2119G>A p.D707N | Missense Mutation (SNP) | VAF 197/425 reads (46%) | SIFT tolerated (0.59); PolyPhen benign (0.068); catalogued as rs759982807, COSV56710683; called by muse, mutect2, varscan2
